Somatic mutation profile of tumor specimen C3N-06996-01 (aliquot CPT0465930006) from CPTAC case C3N-06996, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 60.0 years (21,911 days).
Specimen C3N-06996-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fca5af8e-809a-4642-9960-ae1533be8ac6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-06996-31 (Blood Derived Normal), aliquot CPT0470660006; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b6ef976-46f0-425a-931a-ef609c77922c

The open-access MAF lists 905 somatic variants for this specimen: 581 protein-altering or splice-affecting, 296 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 535, Silent 296, Nonsense Mutation 28, Intron 14, Frame Shift Del 8, RNA 6, Splice Region 4, 5'Flank 4, 3'UTR 3, Splice Site 3, In Frame Del 2, 5'UTR 1.

Variants (750 of 905; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 125/320 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- MLH1 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 101/195 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs63751194, CM011411, CM064120, CS105415, COSV51615553, COSV51616044; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.1826A>C p.N609T | Missense Mutation (SNP) | VAF 131/285 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.053); catalogued as COSV100229302; called by mutect2, varscan2
- AC100868.1 | c.903G>A p.M301I | Missense Mutation (SNP) | VAF 63/284 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs372089338; called by muse, mutect2, varscan2
- ACAN | c.1526C>T p.S509L | Missense Mutation (SNP) | VAF 292/578 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs773794233; called by muse, mutect2, varscan2
- ACAP1 | c.1153G>A p.G385S | Missense Mutation (SNP) | VAF 178/265 reads (67%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs1457600540; called by muse, mutect2, varscan2
- ACSM2B | c.1714G>A p.G572R | Missense Mutation (SNP) | VAF 133/296 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as rs562863484, COSV61658252; called by muse, mutect2, varscan2
- ACSM4 | c.1499C>T p.S500L | Missense Mutation (SNP) | VAF 176/450 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); catalogued as rs936896432, COSV68068440; called by muse, mutect2, varscan2
- ADAMTS9 | c.4780C>T p.R1594C | Missense Mutation (SNP) | VAF 97/397 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.077); catalogued as rs753460041; called by muse, mutect2, varscan2
- AFDN | c.4529G>A p.S1510N | Missense Mutation (SNP) | VAF 195/563 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs974671882, COSV60053663; called by muse, mutect2, varscan2
- AKAP14 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 83/183 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV57631378; called by muse, mutect2, varscan2
- AOC2 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 203/531 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs906351592; called by muse, mutect2, varscan2
- ARHGAP30 | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 75/286 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs149081252; called by muse, mutect2, varscan2
- ASPM | c.7123A>G p.K2375E | Missense Mutation (SNP) | VAF 224/457 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.463); catalogued as rs760715298; called by muse, mutect2, varscan2
- ATF5 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 135/392 reads (34%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.994); catalogued as COSV61311892; called by muse, mutect2, varscan2
- ATG14 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 85/350 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.27); catalogued as rs761169489, COSV55958465; called by muse, mutect2, varscan2
- BBS9 | c.2449G>A p.D817N (on ENST00000242067 / NM_001348036.1; = p.D777N on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 185/469 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.311); catalogued as rs781476538, COSV54158031; called by muse, mutect2, varscan2
- BSPH1 | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 80/330 reads (24%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs559555937, COSV100353747, COSV60412817; called by muse, mutect2, varscan2
- BTAF1 | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 62/205 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as rs750367374, COSV56431009; called by muse, mutect2, varscan2
- C7orf61 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 279/632 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763448516; called by muse, mutect2, varscan2
- CACNA1B | c.6131C>T p.P2044L | Missense Mutation (SNP) | VAF 316/644 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV53152289; called by muse, varscan2
- CACNA1E | c.6592C>T p.Q2198* (on ENST00000367573 / NM_001205293.3; = p.Q2155* on NM_000721.4) | Nonsense Mutation (SNP) | VAF 115/474 reads (24%) | catalogued as COSV100701348, COSV62433984; called by muse, mutect2, varscan2
- CACNA1H | c.2536G>C p.A846P | Missense Mutation (SNP) | VAF 73/360 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62005850; called by muse, mutect2, varscan2
- CALCR | c.118C>T p.L40F | Missense Mutation (SNP) | VAF 227/541 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.407); catalogued as rs1452232507, COSV64006764; called by muse, mutect2, varscan2
- CAND2 | c.1913C>T p.A638V (on ENST00000456430 / NM_001162499.2; = p.A545V on NM_012298.3) | Missense Mutation (SNP) | VAF 118/459 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.677); catalogued as COSV55995191; called by muse, mutect2, varscan2
- CASP8 | c.1055C>T p.P352L (on ENST00000432109 / NM_033355.3; = p.P369L on NM_001228.4) | Missense Mutation (SNP) | VAF 95/240 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51855834; called by muse, mutect2, varscan2
- CCDC15 | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 172/390 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as rs1442012306; called by muse, mutect2, varscan2
- CCDC18 | c.955T>G p.L319V | Missense Mutation (SNP) | VAF 58/228 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.476); catalogued as COSV100159341; called by muse, mutect2
- CCDC73 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 47/168 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58795949; called by muse, mutect2, varscan2
- CCDC81 | c.1010C>T p.S337F (on ENST00000445632 / NM_001156474.2; = p.S247F on NM_021827.4) | Missense Mutation (SNP) | VAF 132/442 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV53576695; called by muse, mutect2, varscan2
- CD163 | c.2105G>A p.R702K | Missense Mutation (SNP) | VAF 146/388 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV100775745; called by muse, mutect2, varscan2
- CD74 | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 263/599 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1015316786; called by muse, mutect2, varscan2
- CDC20B | c.1517C>G p.S506C (on ENST00000381375 / NM_001170402.1; = p.S502C on NM_152623.2) | Missense Mutation (SNP) | VAF 124/367 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs747510518; called by muse, mutect2, varscan2
- CDKN2A | c.202G>C p.A68P | Missense Mutation (SNP) | VAF 481/597 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100448219, COSV58684018; called by muse, mutect2, varscan2
- CDS1 | c.252A>T p.K84N | Missense Mutation (SNP) | VAF 112/257 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as COSV99880786; called by muse, mutect2, varscan2
- CFAP47 | c.6856C>T p.P2286S | Missense Mutation (SNP) | VAF 68/171 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV66216815; called by muse, mutect2, varscan2
- CFAP54 | c.7511G>A p.G2504E | Missense Mutation (SNP) | VAF 136/377 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61570784; called by muse, mutect2, varscan2
- CHD2 | c.1621C>T p.P541S | Missense Mutation (SNP) | VAF 183/352 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV67706875; called by muse, mutect2, varscan2
- CILP | c.2068C>T p.P690S | Missense Mutation (SNP) | VAF 114/461 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.076); catalogued as rs780641361; called by muse, mutect2, varscan2
- CLCA4 | c.893C>T p.S298L | Missense Mutation (SNP) | VAF 90/336 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1420608283, COSV99760656; called by muse, mutect2, varscan2
- CLSTN2 | c.2371C>T p.H791Y | Missense Mutation (SNP) | VAF 124/235 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV71723680; called by muse, mutect2, varscan2
- CNGB3 | c.1596G>A p.M532I | Missense Mutation (SNP) | VAF 53/238 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV60684268; called by muse, mutect2, varscan2
- CNOT1 | c.6890C>T p.T2297M | Missense Mutation (SNP) | VAF 12/286 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as rs1309246092, COSV54699109; called by muse, mutect2
- COL21A1 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 165/340 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs368730001; called by muse, mutect2, varscan2
- COL3A1 | c.3077G>A p.G1026E | Missense Mutation (SNP) | VAF 88/269 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58590774; called by muse, mutect2, varscan2
- COL4A5 | c.875G>A p.G292E | Missense Mutation (SNP) | VAF 205/235 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD107363, CM960347; called by muse, mutect2, varscan2
- COL4A6 | c.998G>A p.G333E | Missense Mutation (SNP) | VAF 127/162 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57869955; called by muse, mutect2, varscan2
- COL5A1 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 93/331 reads (28%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.935); catalogued as rs776904091, COSV65665757; called by muse, mutect2, varscan2
- CPAMD8 | c.1664G>A p.R555Q (on ENST00000651564; = p.R508Q on NM_015692.5) | Missense Mutation (SNP) | VAF 191/518 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as rs556626501, COSV52236438; called by muse, mutect2, varscan2
- CSMD1 | c.1124C>T p.S375L (on ENST00000520002; = p.S374L on NM_033225.6) | Missense Mutation (SNP) | VAF 55/261 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs762593887, COSV68165271; called by muse, mutect2, varscan2
- CSMD3 | c.5267C>T p.P1756L (on ENST00000297405 / NM_001363185.1; = p.P1652L on NM_052900.3) | Missense Mutation (SNP) | VAF 123/235 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV52110625, COSV52128565; called by muse, mutect2, varscan2
- CSMD3 | c.4249C>T p.R1417C (on ENST00000297405 / NM_001363185.1; = p.R1313C on NM_052900.3) | Missense Mutation (SNP) | VAF 64/150 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); catalogued as rs762798837, COSV52206340; called by muse, mutect2, varscan2
- CSRNP3 | c.266G>A p.G89E | Missense Mutation (SNP) | VAF 124/346 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58779283; called by muse, mutect2, varscan2
- DACH1 | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 127/342 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.315); catalogued as COSV57490461; called by muse, mutect2, varscan2
- DACT3 | c.1609C>T p.P537S | Missense Mutation (SNP) | VAF 318/776 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.047); catalogued as rs898355155; called by muse, mutect2, varscan2
- DBX2 | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 51/393 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1237960474; called by muse, mutect2, varscan2
- DCC | c.3709C>T p.P1237S | Missense Mutation (SNP) | VAF 153/325 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101472726; called by muse, mutect2, varscan2
- DDX10 | c.2515A>C p.T839P | Missense Mutation (SNP) | VAF 177/605 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV59441063; called by muse, mutect2, varscan2
- DMBT1 | c.7126G>A p.E2376K (on ENST00000338354 / NM_001377530.1; = p.E1619K on NM_004406.3) | Missense Mutation (SNP) | VAF 189/274 reads (69%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as COSV57536153; called by muse, mutect2, varscan2
- DMKN | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 169/435 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV60089667; called by muse, mutect2, varscan2
- DNAH17 | c.11125G>A p.E3709K | Missense Mutation (SNP) | VAF 172/368 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.625); catalogued as rs760488346, COSV67749672; called by muse, mutect2, varscan2
- DNAH17 | c.8245G>A p.D2749N | Missense Mutation (SNP) | VAF 170/342 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs1000730487; called by muse, mutect2, varscan2
- DNAH2 | c.2104C>T p.R702W | Missense Mutation (SNP) | VAF 154/226 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs140826418; called by muse, mutect2, varscan2
- DNAH9 | c.2121G>A p.M707I | Missense Mutation (SNP) | VAF 94/1023 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs761948731, COSV52343224; called by muse, mutect2
- DPPA5 | c.342G>A p.W114* | Nonsense Mutation (SNP) | VAF 174/413 reads (42%) | catalogued as COSV64875520; called by muse, mutect2, varscan2
- DPYS | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 84/334 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.087); catalogued as rs767616649, COSV60913515; called by muse, mutect2, varscan2
- DYTN | c.1476del p.M494Wfs*6 | Frame Shift Del (DEL) | VAF 113/469 reads (24%) | catalogued as COSV71751953; called by mutect2, pindel, varscan2
- DZIP3 | c.1496C>T p.S499F | Missense Mutation (SNP) | VAF 225/454 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV64312213; called by muse, mutect2, varscan2
- EBF2 | c.1303G>T p.G435W | Missense Mutation (SNP) | VAF 55/289 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV68776035; called by mutect2, varscan2
- EMILIN2 | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 105/395 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as COSV99598231; called by muse, mutect2, varscan2
- ENPP1 | c.2410G>A p.D804N | Missense Mutation (SNP) | VAF 150/240 reads (63%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.651); catalogued as CM050248, COSV62933750; called by muse, mutect2, varscan2
- EP300 | c.3220C>T p.P1074S | Missense Mutation (SNP) | VAF 80/353 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54330276; called by muse, mutect2, varscan2
- EPB41L4A | c.1837C>T p.L613F | Missense Mutation (SNP) | VAF 123/332 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs946537686; called by muse, mutect2, varscan2
- EPHA6 | c.1357G>T p.G453W | Missense Mutation (SNP) | VAF 94/370 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101061108, COSV67579144; called by muse, mutect2, varscan2
- EPHB3 | c.1864C>T p.R622W | Missense Mutation (SNP) | VAF 165/324 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1268552150, COSV57807885; called by muse, mutect2, varscan2
- ERBIN | c.955G>T p.G319W | Missense Mutation (SNP) | VAF 52/290 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99396566; called by muse, mutect2, varscan2
- ERICH3 | c.4184G>A p.G1395E | Missense Mutation (SNP) | VAF 86/378 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.054); catalogued as COSV58612261; called by muse, varscan2
- ETNPPL | c.470G>A p.G157E | Missense Mutation (SNP) | VAF 49/268 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as COSV56595514; called by muse, mutect2, varscan2
- EXTL2 | c.172C>A p.Q58K | Missense Mutation (SNP) | VAF 80/298 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as COSV100921115; called by muse, mutect2, varscan2
- EYS | c.364G>T p.D122Y | Missense Mutation (SNP) | VAF 122/641 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.142); catalogued as COSV60997507, COSV60998944; called by muse, mutect2, varscan2
- FAM135B | c.2156G>A p.R719Q | Missense Mutation (SNP) | VAF 231/459 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as rs750908660, COSV52703573, COSV52705631; called by muse, mutect2, varscan2
- FAM81B | c.625G>A p.G209R | Missense Mutation (SNP) | VAF 150/403 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1340277181, COSV51981746; called by muse, mutect2, varscan2
- FAM83C | c.1585C>T p.P529S | Missense Mutation (SNP) | VAF 272/688 reads (40%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.005); catalogued as rs779328611, COSV100981523; called by muse, mutect2, varscan2
- FBXO3 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 142/426 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1046569134; called by muse, mutect2, varscan2
- FBXO47 | c.1128G>T p.M376I | Missense Mutation (SNP) | VAF 74/415 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV65243029; called by muse, mutect2, varscan2
- FCRL6 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 126/541 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as COSV58942612; called by muse, mutect2, varscan2
- FLT3 | c.2978C>T p.S993L | Missense Mutation (SNP) | VAF 122/351 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.102); catalogued as rs968020606, COSV54043383; called by muse, mutect2, varscan2
- FLT4 | c.2998G>A p.E1000K | Missense Mutation (SNP) | VAF 162/388 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.043); catalogued as rs1189736923; called by muse, mutect2, varscan2
- FNDC11 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 225/615 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs927449253; called by muse, mutect2, varscan2
- FOLH1 | c.1324C>T p.L442F | Missense Mutation (SNP) | VAF 54/344 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57055009; called by muse, mutect2, varscan2
- FRMPD2 | c.1354C>T p.R452W | Missense Mutation (SNP) | VAF 158/254 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141989722; called by muse, mutect2, varscan2
- GABRB2 | c.1117C>T p.R373* | Nonsense Mutation (SNP) | VAF 146/341 reads (43%) | catalogued as rs745319567, COSV50952878; called by muse, mutect2, varscan2
- GATA2 | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 114/542 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.354); catalogued as rs761447305; called by muse, mutect2, varscan2
- GBP7 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 61/208 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.246); catalogued as COSV54009843; called by muse, mutect2, varscan2
- GDA | c.1057C>T p.L353F | Missense Mutation (SNP) | VAF 67/324 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1210696523, COSV52989970; called by muse, mutect2, varscan2
- GGA2 | c.261G>C p.E87D | Missense Mutation (SNP) | VAF 57/200 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1372863814; called by muse, mutect2, varscan2
- GIMAP6 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 226/350 reads (65%) | SIFT tolerated (0.19); PolyPhen benign (0.326); catalogued as COSV61034039; called by muse, mutect2, varscan2
- GLIS2 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 101/458 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.449); catalogued as rs775844299, COSV52111702; called by muse, mutect2, varscan2
- GLT6D1 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 110/491 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs867118146, COSV65627291; called by muse, mutect2, varscan2
- GREM1 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 160/631 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs1312888226; called by muse, mutect2, varscan2
- GRIN2A | c.3787G>A p.G1263R | Missense Mutation (SNP) | VAF 98/456 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs142113044; called by muse, mutect2, varscan2
- GZMB | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 201/386 reads (52%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs763963542, COSV53544040; called by muse, mutect2, varscan2
- HCRTR2 | c.1153G>A p.G385R | Missense Mutation (SNP) | VAF 158/538 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.111); catalogued as rs763502521; called by muse, mutect2, varscan2
- HDAC7 | c.1639C>T p.R547C (on ENST00000427332; = p.R586C on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 110/596 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747546893, COSV50356377; called by muse, mutect2, varscan2
- HEMK1 | c.949C>T p.L317F | Missense Mutation (SNP) | VAF 202/393 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs201118578; called by muse, mutect2, varscan2
- HGF | c.2104C>T p.R702C | Missense Mutation (SNP) | VAF 148/407 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1383506132, COSV55945961, COSV55954460, COSV55959715; called by muse, varscan2
- HHIPL2 | c.258G>A p.M86I | Missense Mutation (SNP) | VAF 187/366 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as rs942269216; called by muse, mutect2, varscan2
- HIVEP3 | c.4400C>T p.P1467L | Missense Mutation (SNP) | VAF 117/433 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs758641818; called by muse, mutect2, varscan2
- HRH1 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 89/441 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.324); catalogued as rs779343203, COSV67955057, COSV67955813; called by muse, mutect2, varscan2
- HYDIN | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 169/241 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753825612, COSV55482951; called by muse, mutect2, varscan2
- IFNA16 | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 71/307 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); catalogued as COSV66510066; called by muse, mutect2, varscan2
- IGHV5-51 | c.19C>T p.L7F | Missense Mutation (SNP) | VAF 46/238 reads (19%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.747); catalogued as rs532191081; called by muse, mutect2, varscan2
- IL4R | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 203/409 reads (50%) | SIFT tolerated (0.82); PolyPhen benign (0.01); catalogued as rs1273255220, COSV50138641; called by muse, mutect2, varscan2
- ITGB4 | c.456G>A p.M152I | Missense Mutation (SNP) | VAF 109/273 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200344164; called by muse, mutect2, varscan2
- ITPR1 | c.7483G>A p.D2495N (on ENST00000354582; = p.D2440N on NM_002222.7) | Missense Mutation (SNP) | VAF 92/391 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs369481606; called by muse, mutect2, varscan2
- JCAD | c.3593C>T p.S1198F | Missense Mutation (SNP) | VAF 229/322 reads (71%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs1317523840; called by muse, mutect2, varscan2
- JPH2 | c.904G>A p.G302S | Missense Mutation (SNP) | VAF 134/726 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100881573; called by muse, mutect2, varscan2
- JUP | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 211/540 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as rs868983797; called by muse, mutect2, varscan2
- KALRN | c.782G>A p.G261D | Missense Mutation (SNP) | VAF 197/433 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV53775163; called by muse, mutect2, varscan2
- KCNB1 | c.286C>T p.L96F | Missense Mutation (SNP) | VAF 245/594 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs34454438; called by muse, mutect2, varscan2
- KCND3 | c.1082C>T p.T361I | Missense Mutation (SNP) | VAF 59/107 reads (55%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.705); catalogued as COSV100138400; called by muse, mutect2, varscan2
- KCNN1 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 243/672 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.136); catalogued as rs1233111160, COSV55842256; called by muse, mutect2, varscan2
- KCNQ5 | c.2503C>A p.L835M | Missense Mutation (SNP) | VAF 55/368 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as rs1034664318; called by muse, mutect2, varscan2
- KDM4E | c.807G>A p.M269I | Missense Mutation (SNP) | VAF 295/632 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs911093601; called by muse, mutect2, varscan2
- KIAA1109 | c.12959G>T p.W4320L | Missense Mutation (SNP) | VAF 81/402 reads (20%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.986); catalogued as COSV99164191; called by muse, mutect2, varscan2
- KLHL13 | c.1888C>T p.R630C | Missense Mutation (SNP) | VAF 213/250 reads (85%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV53245841; called by muse, mutect2, varscan2
- LAMB4 | c.530G>A p.G177E | Missense Mutation (SNP) | VAF 174/451 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs1174200488; called by muse, mutect2, varscan2
- LGR5 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 45/237 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.34); catalogued as rs148289646; called by muse, mutect2, varscan2
- LOXHD1 | c.4735G>A p.E1579K | Missense Mutation (SNP) | VAF 60/304 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); catalogued as rs1411493135, COSV56064367; called by muse, mutect2, varscan2
- LRBA | c.4461G>A p.K1487= | Splice Region (SNP) | VAF 49/154 reads (32%) | catalogued as COSV63956937; called by muse, mutect2, varscan2
- LRP2 | c.12317G>A p.R4106Q | Missense Mutation (SNP) | VAF 61/215 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs537616155, COSV55545814; called by muse, mutect2, varscan2
- LRSAM1 | c.1685C>T p.S562F | Missense Mutation (SNP) | VAF 101/234 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1270040287; called by muse, varscan2
- LY6K | c.76C>G p.R26G | Missense Mutation (SNP) | VAF 169/357 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs782616918, COSV52832216; called by muse, mutect2, varscan2
- MACC1 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 176/477 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.888); catalogued as rs1445967555; called by muse, mutect2, varscan2
- MACROD2 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs867413234, COSV53951516; called by muse, mutect2, varscan2
- MAP3K21 | c.1131G>A p.M377I | Missense Mutation (SNP) | VAF 43/216 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV64047067; called by muse, varscan2
- MCMBP | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 118/170 reads (69%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as rs558629876; called by muse, mutect2, varscan2
- MLIP | c.955C>T p.P319S | Missense Mutation (SNP) | VAF 109/400 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs776438472; called by muse, mutect2, varscan2
- MN1 | c.3058G>A p.D1020N | Missense Mutation (SNP) | VAF 134/546 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.811); catalogued as rs968161766, COSV100180240, COSV56562647; called by muse, mutect2, varscan2
- MRC2 | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 148/379 reads (39%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.922); catalogued as rs560392939, COSV104409348; called by muse, mutect2, varscan2
- MS4A15 | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 191/391 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs765678709, COSV100558953; called by muse, mutect2, varscan2
- MTRF1 | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 66/325 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as rs1467465502, COSV99520890; called by muse, mutect2, varscan2
- MTRF1L | c.866C>A p.T289K | Missense Mutation (SNP) | VAF 50/203 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs766703793; called by muse, mutect2, varscan2
- MUC16 | c.36878G>A p.G12293E | Missense Mutation (SNP) | VAF 132/324 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.64); catalogued as COSV101202233; called by muse, varscan2
- MUC16 | c.14120C>T p.T4707I | Missense Mutation (SNP) | VAF 176/473 reads (37%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.009); catalogued as rs530571737; called by muse, mutect2, varscan2
- MUC16 | c.13790C>T p.S4597F | Missense Mutation (SNP) | VAF 231/548 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.612); catalogued as COSV67454317; called by muse, mutect2, varscan2
- MYOF | c.3469G>A p.D1157N | Missense Mutation (SNP) | VAF 116/192 reads (60%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.469); catalogued as rs1431365033; called by muse, mutect2, varscan2
- NELL1 | c.1472C>T p.A491V | Missense Mutation (SNP) | VAF 146/437 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866526300, COSV54323886; called by muse, mutect2, varscan2
- NLGN4X | c.580G>A p.G194R | Missense Mutation (SNP) | VAF 176/213 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52005118; called by muse, mutect2, varscan2
- NLRP3 | c.2062G>A p.E688K | Missense Mutation (SNP) | VAF 95/433 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs104895414, CM071602, COSV60231611; ClinVar: not provided; called by muse, mutect2, varscan2
- NMUR1 | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 218/446 reads (49%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.012); catalogued as rs1008123206, COSV59403564; called by muse, mutect2, varscan2
- NTAQ1 | c.595C>T p.R199W | Missense Mutation (SNP) | VAF 146/258 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs911948342, COSV54873817; called by muse, varscan2
- NUTM2A | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 230/812 reads (28%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.657); catalogued as rs762216564; called by muse, varscan2
- NWD2 | c.502G>A p.V168M | Missense Mutation (SNP) | VAF 94/425 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1328182426; called by muse, mutect2, varscan2
- OR13F1 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 107/409 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0.192); catalogued as rs140352060; called by muse, mutect2, varscan2
- OR1J4 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 222/432 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.25); catalogued as rs751488742, COSV61590331; called by muse, mutect2, varscan2
- OR2T12 | c.572C>T p.S191L | Missense Mutation (SNP) | VAF 301/597 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as rs138674715; called by muse, mutect2, varscan2
- OR3A2 | c.757C>A p.H253N | Missense Mutation (SNP) | VAF 97/657 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1567539100, COSV101375070, COSV68695262; called by muse, mutect2, varscan2
- OR4A5 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 98/710 reads (14%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.005); catalogued as rs747204814, COSV60523509; called by muse, mutect2, varscan2
- OR4D5 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 181/574 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs138187932; called by muse, mutect2, varscan2
- OR52N5 | c.764C>T p.S255F | Missense Mutation (SNP) | VAF 252/728 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV100399799; called by muse, mutect2, varscan2
- OR56A5 | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 230/688 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.192); catalogued as COSV60827009; called by muse, mutect2, varscan2
- OXCT1 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 93/425 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.535); catalogued as COSV99541980; called by muse, mutect2, varscan2
- PAM | c.2120G>A p.R707Q | Missense Mutation (SNP) | VAF 71/430 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs186632214, COSV57217840; called by muse, mutect2, varscan2
- PCDH18 | c.2770G>A p.V924I | Missense Mutation (SNP) | VAF 123/259 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs1165418870; called by muse, mutect2, varscan2
- PCDHA12 | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 183/461 reads (40%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.07); catalogued as COSV56480390; called by muse, mutect2, varscan2
- PCDHA4 | c.1823C>T p.S608L | Missense Mutation (SNP) | VAF 78/547 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.909); catalogued as rs267600386, COSV63538765; called by muse, varscan2
- PCDHB4 | c.1640G>A p.R547H | Missense Mutation (SNP) | VAF 269/863 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.262); catalogued as rs782104735, COSV52019359; called by muse, mutect2, varscan2
- PCDHB5 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 200/442 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.052); catalogued as rs1554275831, COSV50649076; called by muse, mutect2, varscan2
- PCDHB8 | c.1646G>A p.R549H | Missense Mutation (SNP) | VAF 68/1198 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.344); catalogued as COSV50790749; called by muse, mutect2
- PDXDC1 | c.1915C>T p.R639W | Missense Mutation (SNP) | VAF 120/447 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751281968, COSV55075820; called by muse, mutect2, varscan2
- PGR | c.2387C>T p.S796L | Missense Mutation (SNP) | VAF 189/349 reads (54%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.874); catalogued as COSV54812258; called by muse, mutect2, varscan2
- PIK3C2G | c.4189C>T p.P1397S (on ENST00000676171; = p.P1356S on NM_004570.5) | Missense Mutation (SNP) | VAF 54/285 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.845); catalogued as rs531443561, COSV56813104, COSV99850576; called by muse, mutect2, varscan2
- PLA2G3 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 124/478 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749719925; called by muse, mutect2, varscan2
- PLCB4 | c.2296G>A p.D766N | Missense Mutation (SNP) | VAF 62/201 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99597349; called by muse, mutect2, varscan2
- PLCL2 | c.2287G>T p.G763W (on ENST00000615277 / NM_001144382.2; = p.G637W on NM_015184.5) | Missense Mutation (SNP) | VAF 75/354 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101196954; called by muse, mutect2, varscan2
- PLEKHD1 | c.1183G>A p.D395N | Missense Mutation (SNP) | VAF 186/334 reads (56%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV59448242; called by muse, mutect2, varscan2
- PNMA5 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 260/311 reads (84%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.895); catalogued as COSV100721717, COSV62625766; called by muse, mutect2, varscan2
- POF1B | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 168/213 reads (79%) | SIFT tolerated (0.86); PolyPhen benign (0.198); catalogued as rs142898680, COSV53134057; called by muse, mutect2, varscan2
- POLQ | c.5650C>T p.P1884S | Missense Mutation (SNP) | VAF 134/270 reads (50%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs1016237956; called by muse, mutect2, varscan2
- POTEB3 | c.1051C>T p.H351Y | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as rs1443402115; called by mutect2, varscan2
- PPARGC1A | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 54/243 reads (22%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.996); catalogued as COSV53526292; called by muse, mutect2, varscan2
- PRR32 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 149/325 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as rs1157031173, COSV64420478; called by muse, mutect2, varscan2
- PRRT4 | c.746C>T p.S249L | Missense Mutation (SNP) | VAF 164/397 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs1036124134, COSV101435701; called by muse, mutect2, varscan2
- PRSS1 | c.433G>A p.G145S | Missense Mutation (SNP) | VAF 232/516 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV61197811; called by muse, mutect2, varscan2
- PTPRB | c.4348C>T p.P1450S | Missense Mutation (SNP) | VAF 84/412 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.221); catalogued as rs1265265101, COSV54241336; called by muse, mutect2, varscan2
- PTPRN | c.196G>A p.V66M | Missense Mutation (SNP) | VAF 88/354 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.259); catalogued as rs1474731208; called by muse, mutect2, varscan2
- PVRIG | c.235G>T p.G79C | Missense Mutation (SNP) | VAF 117/614 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs762020992; called by muse, mutect2, varscan2
- RAB9B | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 111/138 reads (80%) | SIFT tolerated (0.07); PolyPhen benign (0.173); catalogued as rs761856500, COSV54587178; called by muse, mutect2, varscan2
- RFC4 | c.676G>A p.G226R | Missense Mutation (SNP) | VAF 55/171 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as rs747555897; called by muse, mutect2, varscan2
- RIC1 | c.2945T>G p.L982R | Missense Mutation (SNP) | VAF 176/365 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1184876499; called by muse, mutect2, varscan2
- RINL | c.1195G>A p.G399R (on ENST00000591812 / NM_001195833.2; = p.G285R on NM_198445.4) | Missense Mutation (SNP) | VAF 305/760 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV61574677; called by muse, mutect2
- RNF182 | c.560G>A p.W187* | Nonsense Mutation (SNP) | VAF 292/561 reads (52%) | catalogued as rs763717759; called by muse, mutect2, varscan2
- ROR2 | c.2015G>A p.R672Q | Missense Mutation (SNP) | VAF 66/303 reads (22%) | catalogued as rs1564222801; called by muse, mutect2, varscan2
- RORC | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 115/350 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as rs199550478, COSV59092062; called by muse, mutect2, varscan2
- RUBCNL | c.1756G>A p.A586T | Missense Mutation (SNP) | VAF 167/435 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.055); catalogued as rs775630155; called by muse, mutect2, varscan2
- SARDH | c.742G>T p.G248W | Missense Mutation (SNP) | VAF 96/397 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100061101; called by muse, mutect2, varscan2
- SBF1 | c.3265C>T p.Q1089* | Nonsense Mutation (SNP) | VAF 101/394 reads (26%) | catalogued as rs1556424255, COSV62368951; called by muse, mutect2, varscan2
- SBF2 | c.5341G>A p.E1781K | Missense Mutation (SNP) | VAF 82/415 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.232); catalogued as COSV56296180, COSV99813073; called by muse, mutect2, varscan2
- SCAF1 | c.2732C>T p.T911I | Missense Mutation (SNP) | VAF 284/682 reads (42%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.009); catalogued as rs748471914; called by muse, mutect2, varscan2
- SCARA3 | c.1546C>T p.R516* | Nonsense Mutation (SNP) | VAF 99/487 reads (20%) | catalogued as rs764235795, COSV57271624; called by muse, mutect2, varscan2
- SCN8A | c.3220G>A p.V1074M | Missense Mutation (SNP) | VAF 108/541 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.34); catalogued as rs776703521; called by muse, mutect2, varscan2
- SDCCAG8 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 66/303 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs1428852073; called by muse, mutect2, varscan2
- SELE | c.1391G>A p.G464E | Missense Mutation (SNP) | VAF 98/390 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1273636695; called by muse, mutect2, varscan2
- SEMA4F | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 65/338 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs542698076; called by muse, mutect2, varscan2
- SEMA5B | c.3253G>A p.G1085R | Missense Mutation (SNP) | VAF 174/312 reads (56%) | SIFT deleterious (0.05); PolyPhen benign (0.354); catalogued as rs372894044; called by muse, mutect2, varscan2
- SF1 | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 89/614 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.037); catalogued as COSV57114019; called by muse, mutect2, varscan2
- SHANK1 | c.64G>A p.G22R | Missense Mutation (SNP) | VAF 278/688 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV99035855; called by muse, mutect2, varscan2
- SIGLEC5 | c.1498G>T p.G500* | Nonsense Mutation (SNP) | VAF 64/355 reads (18%) | catalogued as COSV55783795; called by mutect2, varscan2
- SIGLEC6 | c.743G>A p.G248E | Missense Mutation (SNP) | VAF 146/382 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.562); catalogued as COSV58437059; called by muse, mutect2, varscan2
- SLC5A1 | c.1552C>T p.P518S | Missense Mutation (SNP) | VAF 75/394 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781017057; called by muse, mutect2, varscan2
- SLC5A7 | c.148G>T p.G50C | Missense Mutation (SNP) | VAF 70/285 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs899126759; called by muse, mutect2, varscan2
- SLITRK1 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 86/475 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.094); catalogued as rs374243257; called by muse, mutect2, varscan2
- SMG6 | c.3884G>T p.R1295L | Missense Mutation (SNP) | VAF 75/306 reads (25%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.926); catalogued as COSV99558068; called by muse, mutect2, varscan2
- SMPX | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 161/211 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); catalogued as rs765928656, COSV65277400; called by muse, mutect2, varscan2
- SNTN | c.438G>A p.M146I | Missense Mutation (SNP) | VAF 85/193 reads (44%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); catalogued as COSV59538919; called by muse, mutect2, varscan2
- SNX13 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 119/321 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.101); catalogued as rs761501759; called by muse, mutect2, varscan2
- SP140 | c.2434G>A p.G812S | Missense Mutation (SNP) | VAF 93/313 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs765760187; called by muse, mutect2, varscan2
- SPIB | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 285/792 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.678); catalogued as rs770969995; called by muse, mutect2
- SPTBN4 | c.352C>T p.H118Y | Missense Mutation (SNP) | VAF 169/459 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV58946681; called by muse, mutect2, varscan2
- SQSTM1 | c.998G>A p.G333E | Missense Mutation (SNP) | VAF 73/347 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.716); catalogued as rs755411592; called by muse, mutect2, varscan2
- STOML3 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 125/394 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.313); catalogued as rs753468566, COSV65510775; called by muse, mutect2, varscan2
- STRC | c.361G>A p.G121R | Missense Mutation (SNP) | VAF 42/397 reads (11%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.984); catalogued as rs1322924876; called by muse, mutect2, varscan2
- SULT1C4 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 87/366 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs767218158; called by muse, mutect2, varscan2
- SUPT16H | c.3080C>T p.S1027L | Missense Mutation (SNP) | VAF 88/340 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.036); catalogued as rs749689647, COSV52852226; called by muse, mutect2, varscan2
- SYDE1 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 149/386 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs969260991; called by muse, mutect2, varscan2
- SYN2 | c.1411G>A p.V471M | Missense Mutation (SNP) | VAF 125/569 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.742); catalogued as COSV70286002; called by muse, mutect2, varscan2
- SYNPO | c.1280C>A p.P427Q (on ENST00000394243 / NM_001166208.2; = p.P183Q on NM_007286.6) | Missense Mutation (SNP) | VAF 86/582 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.181); catalogued as rs370323025; called by muse, mutect2, varscan2
- TAS2R39 | c.991C>T p.L331F | Missense Mutation (SNP) | VAF 115/332 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as COSV101489425; called by muse, mutect2, varscan2
- TBC1D10C | c.1264C>T p.R422W | Missense Mutation (SNP) | VAF 308/606 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs763243235; called by muse, mutect2, varscan2
- TBCE | c.391C>T p.P131S (on ENST00000366601; = p.P194S on NM_003193.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 97/194 reads (50%) | SIFT tolerated (0.75); PolyPhen benign (0.426); catalogued as COSV64007073; called by muse, mutect2, varscan2
- TBRG4 | c.1528G>A p.G510S | Missense Mutation (SNP) | VAF 96/534 reads (18%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.707); catalogued as COSV51832302; called by muse, mutect2, varscan2
- TCL1A | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 206/403 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.213); catalogued as COSV68085421; called by muse, mutect2, varscan2
- TCP11X2 | c.839A>G p.N280S | Missense Mutation (SNP) | VAF 166/690 reads (24%) | SIFT tolerated (0.88); PolyPhen benign (0.013); catalogued as rs1490823720; called by muse, mutect2, varscan2
- THSD7B | c.1147C>T p.L383F | Missense Mutation (SNP) | VAF 74/238 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.583); catalogued as rs936570414; called by muse, varscan2
- TLE2 | c.1087G>A p.G363R | Missense Mutation (SNP) | VAF 270/676 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs779771902; called by muse, mutect2, varscan2
- TMCO5A | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 63/252 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV60464150; called by muse, mutect2, varscan2
- TRIM49 | c.1036C>T p.H346Y | Missense Mutation (SNP) | VAF 187/1143 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs866997358, COSV100316023; called by muse, mutect2, varscan2
- TRIR | c.17G>A p.R6K | Missense Mutation (SNP) | VAF 69/355 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); catalogued as rs1166806949; called by muse, mutect2, varscan2
- TRPC6 | c.2672T>C p.I891T | Missense Mutation (SNP) | VAF 78/407 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1565441167; called by muse, mutect2, varscan2
- TRPV5 | c.1250G>A p.G417E | Missense Mutation (SNP) | VAF 103/594 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV54687298; called by muse, mutect2, varscan2
- TSGA10IP | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 161/484 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.098); catalogued as COSV73245429; called by muse, mutect2, varscan2
- TTN | c.75662G>A p.S25221N (on ENST00000591111; = p.S17797N on NM_003319.4) | Missense Mutation (SNP) | VAF 62/196 reads (32%) | PolyPhen probably damaging (0.988); catalogued as rs929588706; called by muse, mutect2, varscan2
- TTN | c.32362G>A p.E10788K (on ENST00000591111; = p.E9861K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/212 reads (28%) | PolyPhen benign (0.003); catalogued as COSV60023517; called by muse, mutect2, varscan2
- TTN | c.26426G>A p.G8809E (on ENST00000591111; = p.G7882E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/260 reads (22%) | PolyPhen probably damaging (1); catalogued as rs1352689756, COSV59963537; called by muse, mutect2, varscan2
- TUBA8 | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 100/362 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.7); catalogued as rs73876568; called by muse, mutect2, varscan2
- UGT3A2 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 100/294 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.173); catalogued as COSV56930766; called by muse, varscan2
- UGT3A2 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 172/441 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as rs149119039, COSV99235954; called by muse, varscan2
- UNC5C | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 79/333 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101497748; called by muse, mutect2, varscan2
- UNC79 | c.6341C>T p.S2114L (on ENST00000393151 / NM_001346218.2; = p.S1937L on NM_020818.5) | Missense Mutation (SNP) | VAF 180/384 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs968285182, COSV56403011; called by muse, mutect2, varscan2
- URB1 | c.3829C>T p.Q1277* | Nonsense Mutation (SNP) | VAF 75/331 reads (23%) | catalogued as rs1427171674; called by muse, mutect2, varscan2
- USH2A | c.3649G>A p.D1217N | Missense Mutation (SNP) | VAF 79/375 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs202247801, COSV56323471, COSV56334875, COSV56376283; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VIL1 | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 125/435 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370393745; called by muse, mutect2, varscan2
- WDFY4 | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 219/327 reads (67%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV57445792; called by muse, mutect2, varscan2
- WDR49 | c.1297C>T p.R433* (on ENST00000308378 / NM_001366158.1; = p.R774* on NM_001348951.2 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 65/303 reads (21%) | catalogued as rs764436533; called by muse, mutect2, varscan2
- WDR87 | c.6088G>A p.E2030K | Missense Mutation (SNP) | VAF 154/392 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.065); catalogued as rs1371104209, COSV58195892; called by muse, mutect2, varscan2
- WIZ | c.4292C>T p.A1431V (on ENST00000673675 / NM_001371589.1; = p.A336V on NM_021241.3) | Missense Mutation (SNP) | VAF 195/532 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.299); catalogued as rs1232838704; called by muse, mutect2, varscan2
- XKR5 | c.1298C>T p.P433L | Missense Mutation (SNP) | VAF 150/339 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as rs753073537; called by muse, mutect2, varscan2
- ZAR1L | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 246/687 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs977237682, COSV61525501; called by muse, mutect2, varscan2
- ZBED6 | c.2314C>T p.P772S | Missense Mutation (SNP) | VAF 98/331 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs913057533; called by muse, mutect2, varscan2
- ZC3H12A | c.1382C>T p.P461L | Missense Mutation (SNP) | VAF 257/485 reads (53%) | SIFT tolerated (0.51); PolyPhen benign (0.019); catalogued as rs1036354045; called by muse, mutect2, varscan2
- ZNF117 | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 79/215 reads (37%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.848); catalogued as rs141982118, COSV51429269; called by muse, mutect2, varscan2
- ZNF287 | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 150/597 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.251); catalogued as COSV101209336; called by muse, mutect2, varscan2
- ZNF717 | c.2437C>T p.P813S | Missense Mutation (SNP) | VAF 104/501 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs78596620, COSV68863605; called by muse, mutect2, varscan2
- ZSCAN18 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 285/647 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773859520; called by muse, mutect2, varscan2
- ZSCAN23 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 79/479 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV99078869; called by muse, mutect2, varscan2
- AC119396.1 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 211/584 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- AC126283.2 | c.1316G>A p.G439E | Missense Mutation (SNP) | VAF 80/378 reads (21%) | SIFT tolerated (0.84); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ACSM2A | c.1704G>A p.W568* (on ENST00000219054; = p.W489* on NM_001308169.2) | Nonsense Mutation (SNP) | VAF 68/318 reads (21%) | called by muse, varscan2
- ADAMTS2 | c.2260C>T p.Q754* | Nonsense Mutation (SNP) | VAF 174/419 reads (42%) | called by muse, mutect2, varscan2
- ADGRE1 | c.2482C>A p.L828M | Missense Mutation (SNP) | VAF 119/557 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ADGRL3 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 49/215 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- ADGRV1 | c.13135G>A p.E4379K | Missense Mutation (SNP) | VAF 148/370 reads (40%) | SIFT tolerated (0.81); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- AFDN | c.955C>T p.L319F | Missense Mutation (SNP) | VAF 95/508 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AKR1B15 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 123/317 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- ALOXE3 | c.1318C>T p.H440Y | Missense Mutation (SNP) | VAF 198/291 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ANHX | c.1066G>A p.D356N | Missense Mutation (SNP) | VAF 72/426 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANKRD20A2P | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- ANKRD35 | c.1870A>C p.N624H | Missense Mutation (SNP) | VAF 112/459 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- ANKRD66 | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 92/619 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- ANLN | c.2236G>A p.D746N | Missense Mutation (SNP) | VAF 83/442 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- ANO8 | c.1724A>G p.D575G | Missense Mutation (SNP) | VAF 130/408 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, varscan2
- ARMH4 | c.1975C>T p.P659S | Missense Mutation (SNP) | VAF 87/470 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATF5 | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 285/690 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- AZI2 | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 80/400 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AZU1 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 200/481 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- BCL11B | c.252C>A p.S84R | Missense Mutation (SNP) | VAF 105/438 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- BPIFA1 | c.46C>A p.Q16K | Missense Mutation (SNP) | VAF 119/668 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- BRD4 | c.506C>T p.T169I | Missense Mutation (SNP) | VAF 103/521 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- C7 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 142/368 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- C8B | c.1288G>A p.G430R | Missense Mutation (SNP) | VAF 211/427 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAMSAP1 | c.4495T>C p.S1499P | Missense Mutation (SNP) | VAF 57/223 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CASP6 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 181/328 reads (55%) | SIFT tolerated (0.21); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CCDC144A | c.1058C>T p.S353F | Missense Mutation (SNP) | VAF 79/562 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- CCDC30 | c.2402C>T p.S801F (on ENST00000340612; = p.S758F on NM_001080850.3) | Missense Mutation (SNP) | VAF 84/373 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- CD96 | c.566G>T p.W189L | Missense Mutation (SNP) | VAF 79/383 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CDCP1 | c.2105C>T p.P702L | Missense Mutation (SNP) | VAF 69/328 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- CDH11 | c.1055T>G p.V352G | Missense Mutation (SNP) | VAF 97/294 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- CENPE | c.1903C>T p.L635F | Missense Mutation (SNP) | VAF 99/340 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- CEP126 | c.1211G>A p.R404K | Missense Mutation (SNP) | VAF 80/565 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CERS3 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- CHD8 | c.7699C>T p.P2567S (on ENST00000646647 / NM_001170629.2; = p.P2288S on NM_020920.4) | Missense Mutation (SNP) | VAF 88/389 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CHRM2 | c.916A>T p.N306Y | Missense Mutation (SNP) | VAF 155/434 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- CIDEA | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 77/309 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- CLASP2 | c.170G>A p.G57D | Missense Mutation (SNP) | VAF 129/269 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CLCN1 | c.1882C>A p.L628M | Missense Mutation (SNP) | VAF 84/399 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CLIC5 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 312/611 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- CLIP1 | c.1046G>A p.G349D | Missense Mutation (SNP) | VAF 182/403 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLSTN2 | c.1736A>C p.N579T | Missense Mutation (SNP) | VAF 185/337 reads (55%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CMAS | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 110/265 reads (42%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- COL14A1 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 84/194 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL27A1 | c.4328C>A p.P1443Q | Missense Mutation (SNP) | VAF 102/461 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL4A1 | c.1312C>T p.P438S | Missense Mutation (SNP) | VAF 158/430 reads (37%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- COL4A3 | c.389G>A p.G130D | Missense Mutation (SNP) | VAF 76/306 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- COL5A3 | c.2827C>T p.P943S | Missense Mutation (SNP) | VAF 209/454 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL6A6 | c.5021G>A p.G1674E | Missense Mutation (SNP) | VAF 63/290 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COLQ | c.557G>A p.G186E | Missense Mutation (SNP) | VAF 66/286 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPNE6 | c.91C>T p.L31F | Missense Mutation (SNP) | VAF 98/484 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CPNE6 | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 90/308 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CPT1C | c.1161G>A p.R387= | Splice Region (SNP) | VAF 210/476 reads (44%) | called by muse, mutect2, varscan2
- CREM | c.407C>T p.P136L (on ENST00000429130; = p.P87L on NM_001881.3) | Missense Mutation (SNP) | VAF 168/237 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- CRYBG3 | c.8579C>T p.T2860I | Missense Mutation (SNP) | VAF 144/293 reads (49%) | SIFT tolerated (0.41); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- CSPG4 | c.192_194del p.L66del | In Frame Del (DEL) | VAF 75/330 reads (23%) | called by mutect2, pindel, varscan2
- CTNND2 | c.3073C>T p.L1025F | Missense Mutation (SNP) | VAF 129/320 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- DAOA | c.34C>A p.Q12K | Missense Mutation (SNP) | VAF 70/415 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- DAPK1 | c.3415C>T p.P1139S | Missense Mutation (SNP) | VAF 263/539 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- DCC | c.926C>T p.T309I | Missense Mutation (SNP) | VAF 71/307 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- DDN | c.2116G>A p.G706R | Missense Mutation (SNP) | VAF 115/310 reads (37%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- DENND1A | c.2555C>T p.A852V | Missense Mutation (SNP) | VAF 105/389 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- DENND2A | c.1591+1G>A p.X531_splice | Splice Site (SNP) | VAF 58/347 reads (17%) | called by muse, mutect2, varscan2
- DGKI | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 124/326 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DIPK1C | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 336/637 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- DISC1 | c.506G>A p.R169K | Missense Mutation (SNP) | VAF 254/467 reads (54%) | SIFT tolerated (0.57); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- DLGAP1 | c.1327C>T p.R443* | Nonsense Mutation (SNP) | VAF 82/294 reads (28%) | called by muse, varscan2
- DNAJC10 | c.1922C>T p.S641L | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- DOCK7 | c.1804A>G p.I602V | Missense Mutation (SNP) | VAF 46/200 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- DPP10 | c.1687C>T p.L563F | Missense Mutation (SNP) | VAF 97/220 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- DSG3 | c.1219G>A p.G407R | Missense Mutation (SNP) | VAF 94/298 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EHMT1 | c.3797C>T p.S1266L | Missense Mutation (SNP) | VAF 275/518 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- EIPR1 | c.895C>T p.L299F | Missense Mutation (SNP) | VAF 319/426 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ELF2 | c.383C>T p.T128I (on ENST00000379550 / NM_001331036.2; = p.T68I on NM_006874.4) | Missense Mutation (SNP) | VAF 67/277 reads (24%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- ELOVL4 | c.727T>A p.F243I | Missense Mutation (SNP) | VAF 227/535 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by mutect2, varscan2
- EPCAM | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 162/212 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EPN3 | c.1889C>A p.P630H | Missense Mutation (SNP) | VAF 166/466 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- F8 | c.4954G>A p.E1652K | Missense Mutation (SNP) | VAF 232/289 reads (80%) | SIFT tolerated (0.55); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FADS1 | c.986C>A p.P329Q | Missense Mutation (SNP) | VAF 248/803 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FAM186A | c.6227C>T p.P2076L | Missense Mutation (SNP) | VAF 98/520 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- FAM186A | c.4468G>A p.E1490K | Missense Mutation (SNP) | VAF 231/894 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.05); called by muse, varscan2
- FAM186A | c.4216G>A p.E1406K | Missense Mutation (SNP) | VAF 240/736 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.03); called by muse, varscan2
- FAM186A | c.2455G>A p.E819K | Missense Mutation (SNP) | VAF 177/483 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- FAM187A | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 157/380 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM237A | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 82/301 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- FAT4 | c.2191G>T p.G731W | Missense Mutation (SNP) | VAF 95/400 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBLN1 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 45/190 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- FCHO1 | c.26G>A p.W9* | Nonsense Mutation (SNP) | VAF 75/413 reads (18%) | called by muse, mutect2, varscan2
- FGFR1 | c.1700G>A p.G567D (on ENST00000447712 / NM_023110.3; = p.G565D on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/311 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FHDC1 | c.2855C>T p.A952V | Missense Mutation (SNP) | VAF 125/440 reads (28%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- FILIP1L | c.3265G>A p.D1089N (on ENST00000354552 / NM_182909.3; = p.D849N on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/324 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.631); called by muse, varscan2
- FMNL2 | c.1829G>A p.G610E | Missense Mutation (SNP) | VAF 50/172 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- FNBP4 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 188/556 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- FOXN4 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 171/451 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FRMPD2 | c.3683C>T p.S1228F | Missense Mutation (SNP) | VAF 86/183 reads (47%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- GALK1 | c.502C>A p.Q168K | Missense Mutation (SNP) | VAF 111/369 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GALNT16 | c.1226G>C p.C409S | Missense Mutation (SNP) | VAF 88/345 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GALNT17 | c.1747C>A p.L583I | Missense Mutation (SNP) | VAF 133/344 reads (39%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- GAST | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 187/506 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- GATA1 | c.449C>A p.P150H | Missense Mutation (SNP) | VAF 166/431 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GBP5 | c.14T>C p.I5T | Missense Mutation (SNP) | VAF 40/250 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- GDF10 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 290/424 reads (68%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- GDF2 | c.940T>A p.L314I | Missense Mutation (SNP) | VAF 254/364 reads (70%) | SIFT tolerated (0.12); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- GIGYF1 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 110/570 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GIPC3 | c.2144C>T p.P715L | Missense Mutation (SNP) | VAF 126/323 reads (39%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- GOLGA8T | c.63G>A p.W21* | Nonsense Mutation (SNP) | VAF 40/202 reads (20%) | called by muse, mutect2, varscan2
- GP2 | c.1544C>A p.P515H (on ENST00000381362 / NM_001007240.3; = p.P512H on NM_001502.4) | Missense Mutation (SNP) | VAF 88/362 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- GPR27 | c.740G>A p.G247D | Missense Mutation (SNP) | VAF 43/182 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GRM8 | c.2396C>T p.P799L | Missense Mutation (SNP) | VAF 144/368 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GUCA1A | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 227/489 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- H2AZ1 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 98/400 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- H3-3B | c.210del p.R70Sfs*3 | Frame Shift Del (DEL) | VAF 104/510 reads (20%) | called by mutect2, pindel, varscan2
- H6PD | c.1595C>T p.P532L | Missense Mutation (SNP) | VAF 216/334 reads (65%) | SIFT tolerated (0.74); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- HDAC4 | c.775A>G p.K259E | Missense Mutation (SNP) | VAF 91/370 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- HERC2 | c.5655T>C p.D1885= | Splice Region (SNP) | VAF 132/259 reads (51%) | called by muse, mutect2, varscan2
- HERC4 | c.1367C>T p.S456L | Missense Mutation (SNP) | VAF 147/218 reads (67%) | SIFT deleterious (0.04); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- HIP1 | c.1619A>C p.Q540P | Missense Mutation (SNP) | VAF 62/342 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- HTR3A | c.1207del p.S403Afs*57 | Frame Shift Del (DEL) | VAF 117/765 reads (15%) | called by mutect2, pindel, varscan2
- IARS2 | c.2507C>T p.P836L | Missense Mutation (SNP) | VAF 167/345 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IFNL1 | c.515A>C p.N172T | Missense Mutation (SNP) | VAF 139/401 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IL1F10 | c.406_408del p.K136del | In Frame Del (DEL) | VAF 77/316 reads (24%) | called by mutect2, pindel, varscan2
- IPP | c.1265A>G p.N422S | Missense Mutation (SNP) | VAF 50/222 reads (23%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- IRAG1 | c.1658C>T p.S553F | Missense Mutation (SNP) | VAF 158/554 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- IRX2 | c.1306G>A p.A436T | Missense Mutation (SNP) | VAF 35/727 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- ITGA9 | c.1214G>A p.G405E | Missense Mutation (SNP) | VAF 66/304 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ITGB4 | c.457G>A p.G153R | Missense Mutation (SNP) | VAF 110/268 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITPR2 | c.2935T>C p.F979L | Missense Mutation (SNP) | VAF 46/247 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- JAKMIP1 | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 91/324 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- JARID2 | c.3117G>A p.M1039I | Missense Mutation (SNP) | VAF 125/404 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- KANK2 | c.1646C>T p.P549L (on ENST00000586659 / NM_001379562.1; = p.P557L on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 123/522 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- KCNB2 | c.1607G>A p.S536N | Missense Mutation (SNP) | VAF 175/345 reads (51%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- KCNH3 | c.3166G>A p.D1056N | Missense Mutation (SNP) | VAF 270/698 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- KCNJ14 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 209/539 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KDM7A | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 198/501 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA1549L | c.2267C>A p.P756Q (on ENST00000321505; = p.P1053Q on NM_012194.3) | Missense Mutation (SNP) | VAF 129/720 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- KIF23 | c.2828C>T p.S943F (on ENST00000260363; = p.S839F on NM_004856.7) | Missense Mutation (SNP) | VAF 178/377 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KLKB1 | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 185/404 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- KNTC1 | c.3147A>C p.E1049D | Missense Mutation (SNP) | VAF 145/702 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KRT6C | c.1318G>A p.D440N | Missense Mutation (SNP) | VAF 114/614 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); called by muse, mutect2
- KRTAP27-1 | c.322G>A p.G108R | Missense Mutation (SNP) | VAF 117/353 reads (33%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- KRTAP9-1 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 90/430 reads (21%) | SIFT deleterious (0.02); called by muse, mutect2, varscan2
- LAMA3 | c.4415G>A p.R1472K | Missense Mutation (SNP) | VAF 69/218 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- LARGE2 | c.1523C>T p.A508V | Missense Mutation (SNP) | VAF 320/649 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LARP1 | c.1070C>T p.T357I (on ENST00000518297 / NM_033551.3; = p.T280I on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 88/384 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- LCE1A | c.298G>A p.G100R | Missense Mutation (SNP) | VAF 138/394 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- LDAH | c.218G>A p.R73K | Missense Mutation (SNP) | VAF 270/388 reads (70%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LEPR | c.3197A>T p.N1066I | Missense Mutation (SNP) | VAF 133/276 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- LMO7 | c.3845C>T p.A1282V (on ENST00000357063; = p.A963V on NM_005358.5) | Missense Mutation (SNP) | VAF 169/430 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- LPO | c.1414C>T p.P472S | Missense Mutation (SNP) | VAF 228/576 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- LRRC37B | c.623T>C p.I208T | Missense Mutation (SNP) | VAF 164/412 reads (40%) | SIFT tolerated (0.78); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- LRRC66 | c.2416C>T p.P806S | Missense Mutation (SNP) | VAF 225/418 reads (54%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- MAP2 | c.2666T>C p.L889S | Missense Mutation (SNP) | VAF 89/417 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- MEGF10 | c.1568A>G p.E523G | Missense Mutation (SNP) | VAF 177/372 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- MEI4 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 274/536 reads (51%) | SIFT tolerated (0.63); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- MGAM2 | c.1570C>T p.H524Y | Missense Mutation (SNP) | VAF 178/412 reads (43%) | SIFT tolerated (0.88); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MICAL2 | c.3759G>A p.W1253* | Nonsense Mutation (SNP) | VAF 137/418 reads (33%) | called by muse, mutect2, varscan2
- MOSPD1 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 154/189 reads (81%) | SIFT deleterious (0.02); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- MROH2B | c.460+1G>A p.X154_splice | Splice Site (SNP) | VAF 120/342 reads (35%) | called by muse, mutect2, varscan2
- MS4A4E | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 198/406 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MUC16 | c.29882G>A p.S9961N | Missense Mutation (SNP) | VAF 72/413 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.263); called by muse, varscan2
- MUC16 | c.17321C>T p.T5774I | Missense Mutation (SNP) | VAF 140/364 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- MUC16 | c.14477C>T p.P4826L | Missense Mutation (SNP) | VAF 68/487 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.035); called by muse, mutect2
- MUC2 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 92/582 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- NALCN | c.5197G>A p.D1733N | Missense Mutation (SNP) | VAF 166/446 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- NCAM1 | c.1426-1G>T p.X476_splice (on ENST00000316851 / NM_181351.5; = p.X466_splice on NM_000615.7) | Splice Site (SNP) | VAF 64/414 reads (15%) | called by mutect2, varscan2
- NDC80 | c.230C>A p.S77Y | Missense Mutation (SNP) | VAF 54/266 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- NEB | c.12561_12573del p.K4188Pfs*57 | Frame Shift Del (DEL) | VAF 49/217 reads (23%) | called by mutect2, pindel, varscan2
- NFRKB | c.1401T>G p.N467K (on ENST00000446488 / NM_001143835.2; = p.N492K on NM_006165.3) | Missense Mutation (SNP) | VAF 253/526 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NLRP1 | c.590G>T p.R197I | Missense Mutation (SNP) | VAF 113/545 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- NLRP5 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 130/313 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NPAP1 | c.1828G>T p.E610* | Nonsense Mutation (SNP) | VAF 77/381 reads (20%) | called by muse, mutect2, varscan2
- NPEPL1 | c.1424C>T p.A475V | Missense Mutation (SNP) | VAF 163/444 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NR3C2 | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 248/447 reads (55%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- NRK | c.3967G>A p.E1323K | Missense Mutation (SNP) | VAF 156/184 reads (85%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NUDT7 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 53/182 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NUP210L | c.3952G>A p.G1318R | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUP98 | c.5371C>T p.P1791S (on ENST00000359171 / NM_001365126.1; = p.P1774S on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 327/687 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NUTM2A | c.421G>A p.G141S | Missense Mutation (SNP) | VAF 69/486 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- NUTM2A | c.422G>A p.G141D | Missense Mutation (SNP) | VAF 71/490 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, varscan2
- NXPH4 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 224/563 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- OR10K1 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 178/354 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- OR14A2 | c.581T>A p.I194N | Missense Mutation (SNP) | VAF 60/246 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); called by mutect2, varscan2
- OR14I1 | c.724C>T p.Q242* | Nonsense Mutation (SNP) | VAF 200/421 reads (48%) | called by muse, mutect2, varscan2
- OR1L3 | c.577T>A p.F193I | Missense Mutation (SNP) | VAF 205/395 reads (52%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.595); called by mutect2, varscan2
- OR3A1 | c.307C>T p.Q103* | Nonsense Mutation (SNP) | VAF 126/843 reads (15%) | called by muse, mutect2, varscan2
- OR4Q2 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 81/290 reads (28%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- OR51L1 | c.911G>A p.G304E | Missense Mutation (SNP) | VAF 62/418 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- OTOG | c.686G>A p.G229E | Missense Mutation (SNP) | VAF 191/388 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- OXCT2 | c.1472C>T p.T491M | Missense Mutation (SNP) | VAF 121/544 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); called by muse, mutect2
- OXSM | c.984G>A p.M328I | Missense Mutation (SNP) | VAF 63/247 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- PABPC1 | c.1309del p.W437Gfs*30 | Frame Shift Del (DEL) | VAF 56/270 reads (21%) | called by mutect2, pindel, varscan2
- PACC1 | c.631C>A p.L211M | Missense Mutation (SNP) | VAF 69/271 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PAH | c.947A>G p.E316G | Missense Mutation (SNP) | VAF 178/417 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- PAPPA | c.2903G>A p.G968D | Missense Mutation (SNP) | VAF 169/348 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH17 | c.3160C>A p.L1054M | Missense Mutation (SNP) | VAF 142/743 reads (19%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- PCDHA3 | c.2329C>T p.P777S | Missense Mutation (SNP) | VAF 111/527 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PCDHAC2 | c.1511T>G p.V504G | Missense Mutation (SNP) | VAF 170/408 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- PCDHB10 | c.1865G>T p.G622V | Missense Mutation (SNP) | VAF 80/912 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHB6 | c.2206G>A p.D736N | Missense Mutation (SNP) | VAF 256/617 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- PCDHB9 | c.1865G>T p.G622V | Missense Mutation (SNP) | VAF 81/642 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PCLO | c.12214G>A p.D4072N | Missense Mutation (SNP) | VAF 222/539 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- PDE1C | c.162G>A p.W54* | Nonsense Mutation (SNP) | VAF 150/381 reads (39%) | called by muse, mutect2, varscan2
- PDE4B | c.120G>A p.W40* | Nonsense Mutation (SNP) | VAF 65/308 reads (21%) | called by muse, mutect2, varscan2
- PGM5 | c.1009G>T p.G337W | Missense Mutation (SNP) | VAF 56/501 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PGR | c.2011C>A p.Q671K | Missense Mutation (SNP) | VAF 273/535 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- PHC3 | c.2432G>A p.R811K (on ENST00000494943 / NM_001308116.2; = p.R823K on NM_024947.4) | Missense Mutation (SNP) | VAF 52/233 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- PHEX | c.1697C>T p.P566L | Missense Mutation (SNP) | VAF 171/211 reads (81%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- PHLDB2 | c.2458T>A p.F820I (on ENST00000393925 / NM_001134439.2; = p.F777I on NM_145753.2) | Missense Mutation (SNP) | VAF 75/284 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PICALM | c.700C>T p.L234F | Missense Mutation (SNP) | VAF 149/330 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PIK3R4 | c.3437C>T p.S1146F | Missense Mutation (SNP) | VAF 47/241 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PITX1 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 96/495 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- PKDREJ | c.4718C>A p.P1573H | Missense Mutation (SNP) | VAF 85/367 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- PKDREJ | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 126/455 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PLA1A | c.362G>T p.W121L | Missense Mutation (SNP) | VAF 123/477 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLEKHG6 | c.655C>T p.H219Y | Missense Mutation (SNP) | VAF 254/622 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PNMA8C | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 147/402 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- POLG | c.262T>A p.F88I | Missense Mutation (SNP) | VAF 102/450 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, varscan2
- POMT2 | c.1634C>T p.S545F | Missense Mutation (SNP) | VAF 152/286 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- POPDC2 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 209/411 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PPIL6 | c.650G>A p.G217E | Missense Mutation (SNP) | VAF 125/300 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- PRMT3 | c.29G>A p.G10D | Missense Mutation (SNP) | VAF 138/426 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (1); called by muse, varscan2
- PRR23C | c.500G>A p.W167* | Nonsense Mutation (SNP) | VAF 156/583 reads (27%) | called by muse, mutect2, varscan2
- PSG5 | c.818G>A p.W273* | Nonsense Mutation (SNP) | VAF 170/440 reads (39%) | called by muse, mutect2, varscan2
- PTGES2 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 90/314 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PXDN | c.2566C>T p.P856S | Missense Mutation (SNP) | VAF 346/436 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RALGAPB | c.1760C>T p.S587L | Missense Mutation (SNP) | VAF 170/455 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- RASIP1 | c.1292C>A p.P431Q | Missense Mutation (SNP) | VAF 123/601 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RBM38 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 193/547 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- RBMS1 | c.179G>A p.S60N | Missense Mutation (SNP) | VAF 90/249 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- RECK | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 75/325 reads (23%) | SIFT tolerated (0.79); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- RGPD4 | c.3046A>T p.N1016Y | Missense Mutation (SNP) | VAF 118/540 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- RGS8 | c.463G>A p.E155K (on ENST00000367556 / NM_001369564.2; = p.E173K on NM_033345.3) | Missense Mutation (SNP) | VAF 189/383 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RHBG | c.1216G>A p.V406M | Missense Mutation (SNP) | VAF 171/377 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- RHOU | c.614C>A p.A205D | Missense Mutation (SNP) | VAF 151/352 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- RIN1 | c.1934C>T p.A645V | Missense Mutation (SNP) | VAF 103/688 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- RPLP0 | c.139C>T p.L47F | Missense Mutation (SNP) | VAF 236/600 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.33); called by muse, mutect2
- RTN1 | c.562C>T p.Q188* | Nonsense Mutation (SNP) | VAF 102/425 reads (24%) | called by muse, mutect2, varscan2
- SAMD7 | c.145C>A p.Q49K | Missense Mutation (SNP) | VAF 85/356 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- SAMD9 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 91/543 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SAMD9L | c.3333G>A p.M1111I | Missense Mutation (SNP) | VAF 136/368 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SBNO2 | c.2120T>G p.V707G | Missense Mutation (SNP) | VAF 168/756 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SCN9A | c.5161C>T p.H1721Y (on ENST00000303354; = p.H1710Y on NM_002977.3) | Missense Mutation (SNP) | VAF 78/284 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by mutect2, varscan2
- SDR16C5 | c.697G>A p.G233S | Missense Mutation (SNP) | VAF 57/184 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SEC14L5 | c.587G>A p.G196E | Missense Mutation (SNP) | VAF 285/548 reads (52%) | SIFT tolerated (0.91); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SELE | c.1634C>A p.P545H | Missense Mutation (SNP) | VAF 77/309 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SH3PXD2B | c.2294C>A p.P765Q | Missense Mutation (SNP) | VAF 118/584 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SHANK3 | c.4721C>T p.P1574L | Missense Mutation (SNP) | VAF 131/521 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- SKOR1 | c.2180C>A p.P727Q | Missense Mutation (SNP) | VAF 117/496 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.102); called by muse, varscan2
- SLC17A3 | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 287/581 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC27A3 | c.1601C>T p.P534L (on ENST00000271857; = p.P406L on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 117/430 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- SLC35F1 | c.217C>T p.L73F | Missense Mutation (SNP) | VAF 158/550 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- SLC6A13 | c.505A>G p.N169D | Missense Mutation (SNP) | VAF 81/425 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- SOBP | c.1546C>T p.P516S | Missense Mutation (SNP) | VAF 231/678 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SOX13 | c.1134G>A p.K378= | Splice Region (SNP) | VAF 95/328 reads (29%) | called by muse, mutect2, varscan2
- SPAG17 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 77/343 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SPHKAP | c.4922T>C p.I1641T (on ENST00000392056 / NM_001142644.2; = p.I1612T on NM_030623.3) | Missense Mutation (SNP) | VAF 12/368 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- SPIDR | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 77/309 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SRD5A3 | c.496G>T p.G166* | Nonsense Mutation (SNP) | VAF 105/402 reads (26%) | called by muse, mutect2, varscan2
- SSX1 | c.425C>A p.P142Q | Missense Mutation (SNP) | VAF 92/193 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- STARD9 | c.13153G>C p.D4385H | Missense Mutation (SNP) | VAF 61/242 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- STAT5A | c.1828A>T p.K610* | Nonsense Mutation (SNP) | VAF 181/443 reads (41%) | called by muse, mutect2, varscan2
- STXBP4 | c.1180C>A p.Q394K | Missense Mutation (SNP) | VAF 49/278 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.576); called by muse, mutect2, varscan2
- SYNE4 | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 142/676 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- TBC1D5 | c.1753G>A p.E585K | Missense Mutation (SNP) | VAF 71/143 reads (50%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- TDRD6 | c.2794G>A p.E932K | Missense Mutation (SNP) | VAF 257/521 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TENM2 | c.3194C>T p.S1065F (on ENST00000518659 / NM_001122679.2; = p.S833F on NM_001080428.3) | Missense Mutation (SNP) | VAF 72/382 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TEP1 | c.7035G>A p.W2345* | Nonsense Mutation (SNP) | VAF 50/248 reads (20%) | called by muse, varscan2
- TFCP2L1 | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 45/167 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- TGIF2LY | c.548C>T p.S183L | Missense Mutation (SNP) | VAF 84/153 reads (55%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- TLDC2 | c.223C>T p.H75Y | Missense Mutation (SNP) | VAF 174/466 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TM4SF4 | c.136A>C p.I46L | Missense Mutation (SNP) | VAF 64/299 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TM4SF5 | c.333del p.L112Sfs*8 | Frame Shift Del (DEL) | VAF 119/1350 reads (9%) | called by mutect2, pindel
- TMC3 | c.1499G>T p.W500L | Missense Mutation (SNP) | VAF 64/309 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TMEM132C | c.1306G>A p.D436N | Missense Mutation (SNP) | VAF 129/311 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); called by muse, mutect2
- TNIP2 | c.815del p.I272Kfs*7 | Frame Shift Del (DEL) | VAF 104/434 reads (24%) | called by mutect2, pindel, varscan2
- TPH2 | c.850C>A p.P284T | Missense Mutation (SNP) | VAF 73/445 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- TSGA10 | c.1600C>T p.Q534* | Nonsense Mutation (SNP) | VAF 39/168 reads (23%) | called by muse, mutect2, varscan2
- TSPAN11 | c.470G>A p.G157E | Missense Mutation (SNP) | VAF 67/318 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTI1 | c.143T>A p.L48H | Missense Mutation (SNP) | VAF 210/513 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.8456C>T p.S2819F (on ENST00000591111; = p.S2773F on NM_003319.4) | Missense Mutation (SNP) | VAF 114/326 reads (35%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UBTF | c.1412C>T p.P471L | Missense Mutation (SNP) | VAF 222/587 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- UHRF1BP1L | c.1159G>A p.G387R | Missense Mutation (SNP) | VAF 179/462 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- UNC13A | c.1154A>T p.E385V | Missense Mutation (SNP) | VAF 269/663 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- UNC79 | c.448G>T p.D150Y | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VARS2 | c.946C>T p.L316F | Missense Mutation (SNP) | VAF 358/755 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- VNN2 | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 104/172 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- VWA5B2 | c.1793G>A p.S598N | Missense Mutation (SNP) | VAF 133/527 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- WASF1 | c.1298C>T p.P433L | Missense Mutation (SNP) | VAF 328/713 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- WASF3 | c.922C>T p.P308S | Missense Mutation (SNP) | VAF 245/591 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- WBP2NL | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 121/253 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- WDR17 | c.3254del p.L1085* | Frame Shift Del (DEL) | VAF 51/296 reads (17%) | called by mutect2, pindel, varscan2
- WRN | c.4240G>A p.G1414R | Missense Mutation (SNP) | VAF 170/341 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- XPO6 | c.2299C>T p.P767S | Missense Mutation (SNP) | VAF 82/371 reads (22%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- YLPM1 | c.1603C>T p.P535S | Missense Mutation (SNP) | VAF 140/539 reads (26%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- YTHDC2 | c.2605C>T p.P869S | Missense Mutation (SNP) | VAF 199/490 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZBTB7A | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 235/636 reads (37%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- ZNF287 | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 364/637 reads (57%) | called by muse, mutect2, varscan2
- ZNF354C | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 128/389 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- ZNF415 | c.1298T>C p.V433A | Missense Mutation (SNP) | VAF 110/629 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- ZNF454 | c.1238G>T p.R413I | Missense Mutation (SNP) | VAF 98/523 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ZNF474 | c.1013G>A p.R338K | Missense Mutation (SNP) | VAF 98/469 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- ZNF517 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 251/470 reads (53%) | SIFT tolerated (0.94); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- ZNF570 | c.66C>G p.D22E | Missense Mutation (SNP) | VAF 57/301 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- ZNF667 | c.491A>G p.N164S | Missense Mutation (SNP) | VAF 204/494 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF680 | c.841C>T p.L281F | Missense Mutation (SNP) | VAF 62/319 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF681 | c.1865G>A p.R622K | Missense Mutation (SNP) | VAF 46/277 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF723 | c.61C>A p.L21M | Missense Mutation (SNP) | VAF 43/304 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF727 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 169/406 reads (42%) | SIFT tolerated (0.67); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZNF730 | c.247C>A p.Q83K | Missense Mutation (SNP) | VAF 52/276 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZNF746 | c.1132C>T p.R378W | Missense Mutation (SNP) | VAF 228/337 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZNF774 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 61/217 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ZNF865 | c.1637C>T p.P546L | Missense Mutation (SNP) | VAF 108/562 reads (19%) | SIFT tolerated (0.43); called by muse, varscan2
- ZSCAN1 | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 234/639 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- ZSCAN5A | c.985G>T p.G329W | Missense Mutation (SNP) | VAF 156/720 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); called by muse, mutect2
- ABCA1 | c.2755C>T p.L919= | Silent (SNP) | VAF 129/431 reads (30%) | catalogued as rs201705347; called by muse, mutect2, varscan2
- ABCA13 | c.3768C>A p.S1256= | Silent (SNP) | VAF 88/412 reads (21%) | catalogued as COSV101330144; called by muse, mutect2, varscan2
- ABCC12 | c.3508C>T p.L1170= | Silent (SNP) | VAF 152/234 reads (65%) | called by muse, mutect2, varscan2
- ABCC5 | c.3042C>T p.F1014= | Silent (SNP) | VAF 95/402 reads (24%) | catalogued as rs1201439815; called by muse, mutect2, varscan2
- ABCF1 | c.1509C>T p.I503= (on ENST00000326195 / NM_001025091.2; = p.I465= on NM_001090.3) | Silent (SNP) | VAF 235/688 reads (34%) | catalogued as rs376861258, COSV58230922; called by muse, mutect2, varscan2
- ABHD18 | c.711C>T p.F237= (on ENST00000398965 / NM_001039717.2; = p.F144= on NM_025097.2 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 34/177 reads (19%) | called by muse, mutect2, varscan2
- ACAN | c.6408C>T p.F2136= | Silent (SNP) | VAF 224/414 reads (54%) | catalogued as rs760076437; called by muse, mutect2, varscan2
- ACOX2 | c.1776C>T p.L592= | Silent (SNP) | VAF 82/371 reads (22%) | called by muse, mutect2, varscan2
- ADAMDEC1 | c.942C>T p.F314= | Silent (SNP) | VAF 41/287 reads (14%) | called by muse, mutect2, varscan2
- ADAMTS14 | c.1764C>T p.G588= | Silent (SNP) | VAF 119/184 reads (65%) | called by muse, mutect2, varscan2
- ADAMTS8 | c.2628C>A p.P876= | Silent (SNP) | VAF 104/608 reads (17%) | catalogued as COSV57298034; called by muse, mutect2, varscan2
- ADGRB3 | c.2143C>T p.L715= | Silent (SNP) | VAF 65/478 reads (14%) | catalogued as rs1311182378; called by muse, mutect2, varscan2
- ADGRE3 | c.1512C>T p.F504= | Silent (SNP) | VAF 151/381 reads (40%) | called by muse, mutect2, varscan2
- AHNAK2 | c.531C>T p.I177= | Silent (SNP) | VAF 101/435 reads (23%) | called by muse, mutect2, varscan2
- ALDH3B1 | c.1089C>T p.A363= | Silent (SNP) | VAF 261/558 reads (47%) | called by muse, mutect2, varscan2
- ALDH5A1 | c.1374C>T p.I458= | Silent (SNP) | VAF 304/572 reads (53%) | catalogued as rs775722631; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMER3 | c.654G>A p.L218= | Silent (SNP) | VAF 113/373 reads (30%) | called by muse, mutect2, varscan2
- AP1M1 | c.171C>T p.F57= | Silent (SNP) | VAF 104/526 reads (20%) | called by muse, mutect2, varscan2
- APC2 | c.3072G>A p.G1024= | Silent (SNP) | VAF 130/668 reads (19%) | called by muse, mutect2, varscan2
- APOL1 | c.954G>A p.V318= | Silent (SNP) | VAF 213/402 reads (53%) | catalogued as COSV59870076; called by muse, mutect2, varscan2
- APOM | c.258T>C p.A86= | Silent (SNP) | VAF 46/593 reads (8%) | catalogued as rs777922967; called by muse, mutect2
- APRT | c.210C>T p.L70= | Silent (SNP) | VAF 86/325 reads (26%) | called by muse, mutect2, varscan2
- ARAP2 | c.3129C>T p.S1043= | Silent (SNP) | VAF 117/430 reads (27%) | called by muse, mutect2, varscan2
- ARHGEF19 | c.1573T>C p.L525= | Silent (SNP) | VAF 140/205 reads (68%) | catalogued as rs751802065; called by muse, mutect2, varscan2
- ARMH3 | c.1668C>T p.I556= | Silent (SNP) | VAF 55/195 reads (28%) | called by muse, mutect2, varscan2
- ATAD2 | c.2511C>T p.S837= | Silent (SNP) | VAF 39/186 reads (21%) | catalogued as rs1443758685; called by muse, mutect2, varscan2
- ATF5 | c.231C>T p.L77= | Silent (SNP) | VAF 136/394 reads (35%) | called by muse, mutect2, varscan2
- ATP13A5 | c.2313G>A p.G771= | Silent (SNP) | VAF 73/237 reads (31%) | called by muse, mutect2, varscan2
- ATRN | c.3780C>T p.F1260= | Silent (SNP) | VAF 42/166 reads (25%) | called by muse, mutect2, varscan2
- BAG3 | c.1686C>A p.P562= | Silent (SNP) | VAF 104/353 reads (29%) | called by muse, mutect2, varscan2
- BHMG1 | c.660G>A p.G220= | Silent (SNP) | VAF 258/609 reads (42%) | called by muse, mutect2, varscan2
- BMPER | c.1368C>T p.I456= | Silent (SNP) | VAF 195/495 reads (39%) | catalogued as COSV51821852; called by muse, mutect2, varscan2
- BRD4 | c.2436C>T p.L812= | Silent (SNP) | VAF 214/495 reads (43%) | called by muse, mutect2, varscan2
- BSN | c.72C>T p.G24= | Silent (SNP) | VAF 56/165 reads (34%) | called by muse, mutect2, varscan2
- BTNL8 | c.783C>T p.F261= | Silent (SNP) | VAF 161/427 reads (38%) | catalogued as COSV51456722; called by muse, mutect2, varscan2
- C11orf91 | c.435G>A p.E145= | Silent (SNP) | VAF 225/648 reads (35%) | called by muse, mutect2, varscan2
- C2CD5 | c.141C>T p.L47= | Silent (SNP) | VAF 41/267 reads (15%) | catalogued as rs571140627; called by muse, mutect2, varscan2
- C3 | c.2025C>G p.L675= | Silent (SNP) | VAF 112/572 reads (20%) | called by muse, mutect2, varscan2
- C4B | c.3915G>A p.T1305= | Silent (SNP) | VAF 174/557 reads (31%) | catalogued as rs1260696251; called by muse, varscan2
- CACNA1E | c.2526G>A p.L842= | Silent (SNP) | VAF 117/549 reads (21%) | catalogued as rs888488253; called by muse, mutect2, varscan2
- CACNA1E | c.4569G>A p.L1523= | Silent (SNP) | VAF 70/312 reads (22%) | catalogued as COSV62423249; called by muse, mutect2, varscan2
- CACNA1I | c.2016G>A p.L672= | Silent (SNP) | VAF 77/323 reads (24%) | called by muse, mutect2, varscan2
- CATSPERD | c.834G>A p.V278= | Silent (SNP) | VAF 64/367 reads (17%) | catalogued as COSV67534310; called by muse, mutect2, varscan2
- CCDC141 | c.96C>T p.V32= | Silent (SNP) | VAF 60/195 reads (31%) | called by muse, mutect2, varscan2
- CCDC17 | c.594G>A p.G198= | Silent (SNP) | VAF 97/425 reads (23%) | called by muse, mutect2, varscan2
- CCDC180 | c.2472G>A p.S824= | Silent (SNP) | VAF 68/270 reads (25%) | catalogued as rs747534952, COSV63829193; called by muse, mutect2
- CCKBR | c.189G>A p.V63= | Silent (SNP) | VAF 155/489 reads (32%) | catalogued as rs868811053; called by muse, mutect2, varscan2
- CCN1 | c.744C>T p.S248= | Silent (SNP) | VAF 173/396 reads (44%) | called by muse, mutect2, varscan2
- CD8B2 | c.651C>T p.F217= | Silent (SNP) | VAF 83/339 reads (24%) | called by muse, mutect2, varscan2
- CFC1 | c.232C>A p.R78= | Silent (SNP) | VAF 85/574 reads (15%) | catalogued as rs1318519716, CM002873; called by muse, mutect2, varscan2
- CFTR | c.2982C>T p.F994= | Silent (SNP) | VAF 28/246 reads (11%) | catalogued as CD160267; called by muse, mutect2, varscan2
- CHD6 | c.3294C>T p.F1098= | Silent (SNP) | VAF 168/392 reads (43%) | called by muse, mutect2, varscan2
- CHST15 | c.81C>T p.P27= | Silent (SNP) | VAF 91/274 reads (33%) | called by muse, mutect2, varscan2
- CIC | c.4392G>A p.R1464= | Silent (SNP) | VAF 207/508 reads (41%) | catalogued as COSV50546528; called by muse, mutect2, varscan2
- CNTN6 | c.1311C>A p.P437= | Silent (SNP) | VAF 97/375 reads (26%) | catalogued as COSV100611107; called by muse, mutect2, varscan2
- COL10A1 | c.897G>A p.G299= | Silent (SNP) | VAF 315/641 reads (49%) | catalogued as COSV54573297; called by muse, mutect2, varscan2
- CPNE6 | c.90C>T p.G30= | Silent (SNP) | VAF 103/485 reads (21%) | called by muse, mutect2, varscan2
- CPSF6 | c.885C>T p.G295= | Silent (SNP) | VAF 130/659 reads (20%) | called by muse, mutect2, varscan2
- CSMD1 | c.10062C>T p.F3354= (on ENST00000520002; = p.F3353= on NM_033225.6) | Silent (SNP) | VAF 125/238 reads (53%) | catalogued as rs376160512; called by muse, mutect2, varscan2
- CSMD1 | c.546C>T p.I182= | Silent (SNP) | VAF 178/360 reads (49%) | catalogued as COSV101225334, COSV68190600; called by muse, mutect2, varscan2
- CSMD2 | c.10275G>A p.A3425= | Silent (SNP) | VAF 176/264 reads (67%) | catalogued as rs759844060, COSV53902268; called by muse, mutect2, varscan2
- CSMD2 | c.4227C>T p.F1409= | Silent (SNP) | VAF 195/282 reads (69%) | called by muse, mutect2, varscan2
- CTNNBL1 | c.1590G>A p.R530= | Silent (SNP) | VAF 69/344 reads (20%) | called by muse, mutect2, varscan2
- CYP4F11 | c.480G>A p.L160= | Silent (SNP) | VAF 139/346 reads (40%) | called by muse, mutect2, varscan2
- CYP4F12 | c.1467C>T p.F489= | Silent (SNP) | VAF 82/369 reads (22%) | catalogued as COSV61175821; called by muse, varscan2
- CYP4F12 | c.1473C>T p.F491= | Silent (SNP) | VAF 69/377 reads (18%) | called by muse, varscan2
- DAB1 | c.681G>A p.K227= | Silent (SNP) | VAF 62/304 reads (20%) | called by muse, mutect2, varscan2
- DBX2 | c.660C>T p.A220= | Silent (SNP) | VAF 51/394 reads (13%) | catalogued as rs557230563, COSV60337408; called by muse, mutect2, varscan2
- DCDC1 | c.2142G>A p.A714= | Silent (SNP) | VAF 111/329 reads (34%) | catalogued as rs768856166, COSV60853901; called by muse, mutect2, varscan2
- DENND1A | c.2556C>T p.A852= | Silent (SNP) | VAF 104/388 reads (27%) | catalogued as rs1045321351; called by muse, mutect2, varscan2
- DGKB | c.1467C>T p.F489= | Silent (SNP) | VAF 197/523 reads (38%) | catalogued as rs1294951423, COSV99341200; called by muse, mutect2, varscan2
- DNAH10 | c.702C>T p.S234= (on ENST00000409039; = p.S173= on NM_207437.3) | Silent (SNP) | VAF 176/468 reads (38%) | called by muse, mutect2, varscan2
- DNAH11 | c.4971C>T p.F1657= | Silent (SNP) | VAF 151/418 reads (36%) | catalogued as rs375997343; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAH5 | c.4365G>A p.K1455= | Silent (SNP) | VAF 109/297 reads (37%) | catalogued as COSV54203749; called by muse, mutect2, varscan2
- DNER | c.456G>A p.Q152= | Silent (SNP) | VAF 105/447 reads (23%) | catalogued as rs1160292459; called by muse, mutect2, varscan2
- DOCK2 | c.1491C>T p.V497= | Silent (SNP) | VAF 145/407 reads (36%) | catalogued as rs758416778; called by muse, mutect2, varscan2
- DOCK5 | c.2394C>T p.F798= | Silent (SNP) | VAF 66/290 reads (23%) | catalogued as COSV52401940; called by muse, mutect2, varscan2
- DRAP1 | c.474C>T p.P158= | Silent (SNP) | VAF 140/440 reads (32%) | called by muse, mutect2, varscan2
- DSCAM | c.3276C>T p.P1092= | Silent (SNP) | VAF 222/291 reads (76%) | catalogued as rs767777598; called by muse, mutect2, varscan2
- DUSP8 | c.66C>T p.G22= | Silent (SNP) | VAF 160/879 reads (18%) | catalogued as rs776913438; called by muse, mutect2, varscan2
- ELOVL4 | c.726C>T p.P242= | Silent (SNP) | VAF 228/538 reads (42%) | catalogued as rs1362199740; called by mutect2, varscan2
- EPN3 | c.1890C>T p.P630= | Silent (SNP) | VAF 144/434 reads (33%) | called by muse, varscan2
- ERICH3 | c.4309C>T p.L1437= | Silent (SNP) | VAF 104/452 reads (23%) | called by muse, varscan2
- ETFB | c.322C>T p.L108= | Silent (SNP) | VAF 212/599 reads (35%) | catalogued as rs1273867982; called by muse, mutect2, varscan2
- EXOC3L2 | c.1191G>A p.L397= | Silent (SNP) | VAF 68/353 reads (19%) | catalogued as rs770491427; called by muse, mutect2, varscan2
- FAM186A | c.4215G>A p.Q1405= | Silent (SNP) | VAF 234/742 reads (32%) | called by muse, varscan2
- FAM220A | c.570C>T p.S190= | Silent (SNP) | VAF 156/471 reads (33%) | called by muse, mutect2, varscan2
- FBXO15 | c.1482C>T p.V494= | Silent (SNP) | VAF 154/349 reads (44%) | catalogued as rs1461442703, COSV54048825; called by muse, mutect2, varscan2
- FKRP | c.168C>T p.F56= | Silent (SNP) | VAF 138/651 reads (21%) | catalogued as rs1443120812, COSV59358412; called by muse, varscan2
- FOLH1 | c.1323C>T p.L441= | Silent (SNP) | VAF 52/341 reads (15%) | catalogued as COSV57056789; called by muse, mutect2, varscan2
- FOXB2 | c.681G>C p.A227= | Silent (SNP) | VAF 88/320 reads (28%) | catalogued as rs766927262; called by muse, varscan2
- FOXI1 | c.471C>T p.F157= | Silent (SNP) | VAF 116/649 reads (18%) | called by muse, mutect2, varscan2
- FRMD7 | c.2085C>T p.F695= | Silent (SNP) | VAF 197/248 reads (79%) | called by muse, mutect2, varscan2
- FRMPD3 | c.5232A>G p.T1744= | Silent (SNP) | VAF 276/338 reads (82%) | called by muse, mutect2, varscan2
- FRMPD4 | c.3168G>A p.E1056= | Silent (SNP) | VAF 283/346 reads (82%) | called by muse, mutect2, varscan2
- GALNT16 | c.1227C>T p.C409= | Silent (SNP) | VAF 88/345 reads (26%) | catalogued as rs762891847; called by muse, mutect2, varscan2
- GAPDH | c.981C>T p.L327= | Silent (SNP) | VAF 151/398 reads (38%) | called by muse, mutect2, varscan2
- GCDH | c.249C>T p.I83= | Silent (SNP) | VAF 80/307 reads (26%) | catalogued as rs1013749296, COSV53435411; called by muse, mutect2, varscan2
- GCNT3 | c.81G>A p.L27= | Silent (SNP) | VAF 70/322 reads (22%) | catalogued as rs376109646; called by muse, mutect2, varscan2
- GIGYF1 | c.84C>T p.S28= | Silent (SNP) | VAF 206/511 reads (40%) | catalogued as rs766066536, COSV51943531; called by muse, mutect2, varscan2
- GPR32 | c.15G>A p.S5= | Silent (SNP) | VAF 57/295 reads (19%) | catalogued as rs756485883, COSV54514044; called by muse, mutect2, varscan2
- GPR65 | c.135G>A p.K45= | Silent (SNP) | VAF 161/313 reads (51%) | catalogued as rs1164804822; called by muse, mutect2, varscan2
- GPR84 | c.417G>A p.L139= | Silent (SNP) | VAF 82/498 reads (16%) | called by muse, mutect2, varscan2
- GRAMD1A | c.1860C>T p.I620= | Silent (SNP) | VAF 120/356 reads (34%) | called by muse, mutect2, varscan2
- HERC2 | c.3867C>T p.I1289= | Silent (SNP) | VAF 56/203 reads (28%) | catalogued as rs4078593; called by muse, mutect2, varscan2
- HGF | c.2043A>G p.Q681= | Silent (SNP) | VAF 150/358 reads (42%) | called by muse, varscan2
- HNF4A | c.702G>A p.K234= | Silent (SNP) | VAF 189/499 reads (38%) | called by muse, mutect2, varscan2
- HPCAL4 | c.102C>T p.F34= | Silent (SNP) | VAF 108/447 reads (24%) | called by muse, mutect2, varscan2
- HYDIN | c.2298G>T p.L766= | Silent (SNP) | VAF 67/257 reads (26%) | called by muse, mutect2, varscan2
- IFNL1 | c.124C>T p.L42= | Silent (SNP) | VAF 170/447 reads (38%) | catalogued as rs772112795, COSV100373680; called by muse, mutect2, varscan2
- IGHV5-51 | c.18C>T p.I6= | Silent (SNP) | VAF 46/234 reads (20%) | catalogued as rs782435199; called by muse, mutect2, varscan2
- INPP5D | c.1693C>T p.L565= (on ENST00000445964 / NM_001017915.3; = p.L564= on NM_005541.5) | Silent (SNP) | VAF 69/331 reads (21%) | called by muse, mutect2, varscan2
- ITGA7 | c.2028C>T p.F676= (on ENST00000555728; = p.F632= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 49/299 reads (16%) | called by muse, mutect2, varscan2
- ITIH1 | c.1230G>A p.V410= | Silent (SNP) | VAF 136/266 reads (51%) | called by muse, mutect2, varscan2
- ITPR1 | c.6195C>T p.I2065= (on ENST00000354582; = p.I2010= on NM_002222.7) | Silent (SNP) | VAF 126/280 reads (45%) | called by muse, mutect2, varscan2
- JAK3 | c.2145C>T p.V715= | Silent (SNP) | VAF 251/586 reads (43%) | called by muse, mutect2, varscan2
- KCNB2 | c.735C>T p.T245= | Silent (SNP) | VAF 213/424 reads (50%) | catalogued as rs1456526969; called by muse, varscan2
- KCNN2 | c.1089C>T p.D363= (on ENST00000264773; = p.D575= on NM_021614.4) | Silent (SNP) | VAF 54/465 reads (12%) | catalogued as COSV53286727; called by muse, mutect2, varscan2
- KCNN3 | c.1681C>T p.L561= (on ENST00000618040 / NM_001204087.1; = p.L546= on NM_002249.6) | Silent (SNP) | VAF 70/219 reads (32%) | called by muse, mutect2, varscan2
- KIAA2012 | c.465G>A p.K155= | Silent (SNP) | VAF 102/337 reads (30%) | called by muse, mutect2, varscan2
- KIF26A | c.273C>A p.P91= | Silent (SNP) | VAF 79/355 reads (22%) | catalogued as rs746731733, COSV59466683; called by muse, mutect2, varscan2
- KL | c.2436C>T p.I812= | Silent (SNP) | VAF 185/444 reads (42%) | catalogued as COSV66309465; called by muse, mutect2, varscan2
- KRT31 | c.951G>A p.L317= | Silent (SNP) | VAF 313/786 reads (40%) | called by muse, mutect2, varscan2
- KRT85 | c.1356C>T p.V452= | Silent (SNP) | VAF 87/446 reads (20%) | catalogued as COSV57736959; called by muse, mutect2, varscan2
- KSR2 | c.2787G>A p.E929= | Silent (SNP) | VAF 176/448 reads (39%) | called by muse, mutect2, varscan2
- KSR2 | c.1965C>T p.F655= | Silent (SNP) | VAF 129/563 reads (23%) | catalogued as rs1295958309, COSV56664593; called by muse, mutect2, varscan2
- L3MBTL4 | c.24G>A p.R8= | Silent (SNP) | VAF 48/232 reads (21%) | catalogued as COSV53115543; called by muse, mutect2, varscan2
- LAMA1 | c.7929C>T p.F2643= | Silent (SNP) | VAF 65/303 reads (21%) | catalogued as COSV67540321; called by muse, mutect2, varscan2
- LAMA1 | c.4422C>T p.F1474= | Silent (SNP) | VAF 146/272 reads (54%) | catalogued as rs1374231375; called by muse, mutect2, varscan2
- LAMB1 | c.2361C>T p.P787= | Silent (SNP) | VAF 181/460 reads (39%) | called by muse, mutect2, varscan2
- LAMB3 | c.561G>A p.G187= | Silent (SNP) | VAF 125/254 reads (49%) | catalogued as COSV61915403; called by muse, mutect2, varscan2
- LAS1L | c.1440C>T p.L480= | Silent (SNP) | VAF 91/233 reads (39%) | called by muse, mutect2, varscan2
- LCE2D | c.54C>A p.P18= | Silent (SNP) | VAF 106/352 reads (30%) | catalogued as COSV100909507, COSV64228907; called by mutect2, varscan2
- LEMD1 | c.432C>T p.I144= (on ENST00000367151; = p.S97L on NM_001001552.5) | Silent (SNP) | VAF 118/454 reads (26%) | catalogued as rs1291750813; called by muse, varscan2
- LGSN | c.810C>T p.F270= | Silent (SNP) | VAF 172/445 reads (39%) | called by muse, mutect2, varscan2
- LIFR | c.2733G>A p.L911= | Silent (SNP) | VAF 64/371 reads (17%) | called by muse, mutect2, varscan2
- LRRC4B | c.1932G>T p.V644= | Silent (SNP) | VAF 161/810 reads (20%) | called by muse, mutect2, varscan2
- LRRC74A | c.1062C>T p.I354= | Silent (SNP) | VAF 71/242 reads (29%) | called by muse, mutect2, varscan2
- LRRC75B | c.342C>T p.C114= | Silent (SNP) | VAF 71/339 reads (21%) | called by muse, mutect2, varscan2
- LRSAM1 | c.1686C>T p.S562= | Silent (SNP) | VAF 112/251 reads (45%) | called by muse, mutect2, varscan2
- LTBP2 | c.1035G>A p.T345= | Silent (SNP) | VAF 74/264 reads (28%) | catalogued as rs753472367, COSV100000908, COSV56211509; called by muse, mutect2, varscan2
- MAGEC3 | c.417G>A p.K139= | Silent (SNP) | VAF 296/371 reads (80%) | catalogued as rs1174724825; called by muse, mutect2, varscan2
- MARCHF2 | c.504G>A p.R168= | Silent (SNP) | VAF 252/628 reads (40%) | called by muse, varscan2
- ME2 | c.312T>A p.I104= | Silent (SNP) | VAF 55/272 reads (20%) | catalogued as COSV58422185; called by muse, mutect2, varscan2
- MECOM | c.2502G>A p.A834= (on ENST00000468789 / NM_001105078.4; = p.A1022= on NM_004991.4) | Silent (SNP) | VAF 162/326 reads (50%) | catalogued as rs779331325, COSV52958403; called by muse, varscan2
- MEGF8 | c.3732C>T p.L1244= (on ENST00000251268 / NM_001271938.2; = p.L1177= on NM_001410.3) | Silent (SNP) | VAF 239/543 reads (44%) | catalogued as rs760828598; called by muse, mutect2, varscan2
- MKRN3 | c.495C>T p.S165= | Silent (SNP) | VAF 136/550 reads (25%) | catalogued as rs747691232; called by muse, mutect2, varscan2
- MMP26 | c.51C>A p.A17= | Silent (SNP) | VAF 82/533 reads (15%) | called by muse, varscan2
- MRGPRX4 | c.186C>T p.S62= | Silent (SNP) | VAF 203/677 reads (30%) | catalogued as rs754405552, COSV100049872, COSV58591257; called by muse, mutect2, varscan2
- MROH2B | c.2838C>T p.I946= | Silent (SNP) | VAF 83/411 reads (20%) | catalogued as rs1466657560; called by muse, mutect2, varscan2
- MTSS2 | c.1059C>T p.S353= | Silent (SNP) | VAF 74/203 reads (36%) | catalogued as rs764224417; called by muse, mutect2, varscan2
- MUC16 | c.37011G>A p.L12337= | Silent (SNP) | VAF 51/320 reads (16%) | called by muse, varscan2
- MUC16 | c.29805C>T p.I9935= | Silent (SNP) | VAF 172/404 reads (43%) | called by muse, varscan2
- MUC5B | c.12252G>A p.T4084= | Silent (SNP) | VAF 347/1120 reads (31%) | catalogued as rs776423255, COSV71595548; called by muse, mutect2, varscan2
- MYBPC2 | c.2289C>T p.I763= | Silent (SNP) | VAF 186/527 reads (35%) | catalogued as rs775231133, COSV63093660; called by muse, mutect2, varscan2
- MYO7A | c.2439C>T p.A813= | Silent (SNP) | VAF 143/860 reads (17%) | called by muse, mutect2, varscan2
- MYOCD | c.1593C>T p.L531= | Silent (SNP) | VAF 220/549 reads (40%) | catalogued as rs149724951, COSV100590348; called by muse, mutect2, varscan2
- MYOZ3 | c.150C>T p.L50= | Silent (SNP) | VAF 96/433 reads (22%) | called by muse, mutect2, varscan2
- NFE2 | c.414C>T p.P138= | Silent (SNP) | VAF 245/565 reads (43%) | catalogued as COSV56457369; called by muse, mutect2, varscan2
- NGLY1 | c.1449C>T p.P483= | Silent (SNP) | VAF 90/203 reads (44%) | called by muse, mutect2, varscan2
- NLRP2 | c.411G>A p.T137= | Silent (SNP) | VAF 61/282 reads (22%) | catalogued as rs756188251, COSV54753405; called by muse, mutect2, varscan2
- NLRP3 | c.2238C>T p.L746= | Silent (SNP) | VAF 111/358 reads (31%) | catalogued as COSV60227180; called by muse, mutect2, varscan2
- NLRP8 | c.2682G>T p.L894= | Silent (SNP) | VAF 77/391 reads (20%) | called by muse, mutect2, varscan2
- NPAP1 | c.252C>T p.V84= | Silent (SNP) | VAF 293/569 reads (51%) | catalogued as COSV100276158; called by muse, mutect2, varscan2
- NPEPL1 | c.1425C>T p.A475= | Silent (SNP) | VAF 151/419 reads (36%) | called by muse, varscan2
- NPY1R | c.165C>T p.V55= | Silent (SNP) | VAF 84/359 reads (23%) | catalogued as rs1444107964; called by muse, mutect2, varscan2
- NRBP1 | c.1225C>T p.L409= | Silent (SNP) | VAF 241/338 reads (71%) | called by muse, mutect2, varscan2
- NYNRIN | c.2034C>A p.P678= | Silent (SNP) | VAF 83/395 reads (21%) | called by mutect2, varscan2
- OCM2 | c.255C>T p.S85= | Silent (SNP) | VAF 117/370 reads (32%) | catalogued as COSV99990854, COSV99990858; called by muse, mutect2, varscan2
155 further variants in this file (0 protein-altering or splice-affecting, 127 silent, 28 other) are not listed here.
